Gene-level copy-number profile of tumor specimen MP2PRT-PANVIB-TMP1-A from MP2PRT case MP2PRT-PANVIB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,040 days).
Specimen MP2PRT-PANVIB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4ed892d8-35b0-4496-bf1f-ba7d84b61372.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PANVIB-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/ac5df22a-154f-4f53-8976-2d14c6b1f580

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 2,485; copy number 2: 42,078; copy number 3: 11,529; copy number 4: 2,066; copy number 5: 642; copy number 6: 57; copy number 7: 11.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:26,158,146–26,206,038, 12 genes: H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 710 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:168,053,166–168,101,511, 1 gene, copy number 5: FRMD1.
- chr10:132,783,179–132,786,147, 1 gene, copy number 5 (within-gene range 3–5): NKX6-2.
- chr10:132,943,967–133,131,675, 5 genes, copy number 5–6 (within-gene range 3–6): LINC01166, LINC01167, LINC01168, ADGRA1, ADGRA1-AS1.
- chr14:18,333,726–18,650,966, 15 genes, copy number 6 (within-gene range 4–6): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12.
- chr14:22,265,749–22,272,563, 2 genes, copy number 5: TRAV37, TRAV38-1.
- chr14:101,217,372–101,731,108, 12 genes, copy number 5 (within-gene range 2–5): AL355836.1, AL359682.1, AL355096.1, LINC00524, LINC02314, AL049836.2, DIO3OS, MIR1247, DIO3, AL049836.1, LINC02320, AL355032.1.
- chr14:104,400,943–104,605,647, 5 genes, copy number 6: RNU6-684P, CEND1P1, TMEM179, C14orf180, BX927359.1.
- chr16:1,064,093–1,113,399, 6 genes, copy number 5: SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1.
- chr21:9,325,013–33,170,649, 378 genes, copy number 5–7 (broad region; genes not listed).
- chr21:36,156,782–36,294,274, 1 gene, copy number 5 (within-gene range 3–5): DOP1B.
- chr21:36,295,173–46,132,848, 283 genes, copy number 5–7 (broad region; genes not listed).
- chr22:15,635,180–15,644,330, 1 gene, copy number 6: MED15P7.

Autosomal genes at a single copy (total copy number 1): 1,911. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
